Somatic mutation profile of tumor specimen TCGA-LT-A5Z6-01A (aliquot TCGA-LT-A5Z6-01A-11D-A289-08) from TCGA case TCGA-LT-A5Z6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 56.8 years (20,746 days).
Specimen TCGA-LT-A5Z6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc91a12-8123-484c-8855-579e6dd68ed6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LT-A5Z6-10A (Blood Derived Normal), aliquot TCGA-LT-A5Z6-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45f27fa1-b1a3-42a5-9573-068e743aa35c

The open-access MAF lists 592 somatic variants for this specimen: 412 protein-altering or splice-affecting, 170 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 356, Silent 170, Nonsense Mutation 47, Intron 5, RNA 5, Splice Region 3, Splice Site 3, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.832C>T p.R278* (on ENST00000281708 / NM_001349798.2; = p.R198* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 30/38 reads (79%) | hotspot (GDC flag); catalogued as COSV55891638; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 59/74 reads (80%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AACS | c.1125C>G p.I375M | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV55536890; called by muse, mutect2, varscan2
- AC068580.4 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52588336; called by muse, mutect2, varscan2
- ACP5 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV54536259, COSV54536728; called by muse, mutect2, varscan2
- ACTR8 | c.1098G>C p.Q366H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99213505; called by muse, mutect2
- ADCY2 | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57873811; called by muse, mutect2, varscan2
- AFF1 | c.2273C>A p.P758Q | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV57119990; called by muse, mutect2
- AHR | c.1149G>C p.Q383H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- AK9 | c.4881C>G p.I1627M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69851385; called by muse, mutect2, varscan2
- AKAP6 | c.2165C>G p.S722C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55214513; called by muse, mutect2, varscan2
- ALOX12 | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV52350054; called by muse, mutect2, varscan2
- AMY2B | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV63715076; called by muse, mutect2, varscan2
- ANK2 | c.5005C>A p.L1669M | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.179); catalogued as COSV52162389, COSV52183833; called by muse, mutect2, varscan2
- ANKRD12 | c.5116G>T p.E1706* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV100040559, COSV100041208; called by muse, mutect2
- ANKRD16 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.202); catalogued as COSV51947493; called by muse, varscan2
- ANKRD49 | c.182A>G p.E61G | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV57060143; called by muse, mutect2, varscan2
- AP000311.1 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.07); catalogued as rs1285959370, COSV51708419; called by muse, mutect2, varscan2
- ARG2 | c.869C>A p.S290* | Nonsense Mutation (SNP) | VAF 37/94 reads (39%) | catalogued as COSV99373626; called by muse, mutect2, varscan2
- ARHGAP35 | c.2924C>G p.S975* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV101350602, COSV101350643; called by muse, mutect2, varscan2
- ARHGEF16 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as rs1347673148, COSV101000318; called by muse, mutect2
- ARRDC1 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as COSV65060024; called by muse, mutect2, varscan2
- ASIP | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV66588372; called by muse, mutect2, varscan2
- ATP2C1 | c.295C>T p.Q99* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100146180; called by muse, mutect2, varscan2
- BCL9L | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 17/305 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52684643; called by muse, mutect2
- BCR | c.2971G>A p.G991S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); catalogued as rs1021876865, COSV59931524; called by muse, mutect2
- BMP2K | c.3151G>T p.D1051Y | Missense Mutation (SNP) | VAF 43/459 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs762599499, COSV55009866; called by muse, mutect2
- BNC1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.754); catalogued as COSV61757560; called by muse, mutect2, varscan2
- BRAT1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs779338983, COSV61395418; called by muse, mutect2, varscan2
- BRD2 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV66373377; called by muse, mutect2
- BRSK2 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV57543410; called by muse, mutect2, varscan2
- C12orf50 | c.961C>G p.H321D | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV53893453, COSV53895446; called by muse, mutect2, varscan2
- C1orf56 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54847059; called by muse, mutect2, varscan2
- CACNA1B | c.1038C>A p.F346L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53127082, COSV53150083; called by muse, mutect2
- CACNA1G | c.6706G>A p.E2236K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365654646, COSV61728093; called by muse, mutect2, varscan2
- CAPN12 | c.965G>T p.W322L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61016218; called by muse, mutect2
- CARD11 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 40/91 reads (44%) | catalogued as COSV101210461; called by muse, mutect2, varscan2
- CARMIL1 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV100277042, COSV61517774; called by muse, mutect2, varscan2
- CBS | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM940222, COSV61443180; called by muse, mutect2, varscan2
- CCAR1 | c.2056G>C p.E686Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV56269993, COSV99770505; called by muse, mutect2, varscan2
- CCDC102B | c.1470G>C p.Q490H | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60134812, COSV60142402; called by muse, mutect2, varscan2
- CCDC6 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as rs778657226, COSV54056771; called by mutect2, varscan2
- CCDC85A | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.753); catalogued as COSV101339339; called by muse, mutect2
- CCDC91 | c.530A>G p.K177R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1248847943, COSV60342494; called by muse, mutect2, varscan2
- CCL21 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 9/98 reads (9%) | catalogued as COSV99425527; called by muse, mutect2
- CCT6B | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV100030392; called by muse, mutect2
- CCT7 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54584750; called by muse, mutect2
- CD163L1 | c.873G>A p.W291* | Nonsense Mutation (SNP) | VAF 11/131 reads (8%) | catalogued as COSV58026406; called by muse, mutect2
- CD163L1 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV58016695; called by muse, mutect2
- CD1E | c.1079C>G p.S360* | Nonsense Mutation (SNP) | VAF 56/118 reads (47%) | catalogued as rs775676287, COSV100936885, COSV63772865; called by muse, mutect2, varscan2
- CDC20B | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57050272, COSV57052695; called by muse, mutect2
- CDH23 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54935257, COSV54957250; called by muse, mutect2, varscan2
- CDH9 | c.2362C>G p.R788G | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs1490430616, COSV50290487, COSV50355055; called by muse, mutect2, varscan2
- CDHR3 | c.2437G>C p.E813Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV100487867; called by muse, mutect2
- CDK20 | c.631G>A p.E211K (on ENST00000325303 / NM_001039803.3; = p.E190K on NM_012119.4) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV57482766; called by muse, mutect2
- CDON | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV54998142, COSV99701783; called by muse, mutect2
- CELSR3 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770585899, COSV50841296, COSV50842619; called by muse, mutect2
- CENPJ | c.1938G>C p.E646D | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV67883457; called by muse, mutect2, varscan2
- CEP19 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV56359846; called by muse, mutect2, varscan2
- CEP350 | c.5512G>A p.E1838K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1177981919, COSV62602924; called by muse, mutect2, varscan2
- CHDH | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 82/189 reads (43%) | catalogued as COSV100179517, COSV59459427; called by muse, varscan2
- CHMP2A | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53396942; called by muse, mutect2, varscan2
- CLEC3B | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as COSV56109850, COSV56110404; called by muse, mutect2
- CLK2 | c.1143C>A p.F381L (on ENST00000368361 / NM_001294339.2; = p.F380L on NM_003993.4) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56945275; called by muse, mutect2, varscan2
- CLK4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1331037485, COSV60318848; called by muse, mutect2, varscan2
- CLOCK | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV59402036; called by muse, mutect2, varscan2
- CNTN3 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.791); catalogued as COSV55171806; called by muse, mutect2, varscan2
- CNTN3 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs745699942, COSV55165800; called by muse, mutect2, varscan2
- CNTROB | c.1788G>C p.E596D | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV66608207; called by muse, mutect2, varscan2
- COBLL1 | c.850C>T p.R284C (on ENST00000392717; = p.R246C on NM_014900.5) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553945564, COSV52068219; called by muse, mutect2, varscan2
- COL2A1 | c.3284G>A p.G1095D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61530880; called by muse, mutect2, varscan2
- COL4A2 | c.4399G>C p.E1467Q | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV64628507; called by muse, varscan2
- COL6A6 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV62025916; called by muse, mutect2, varscan2
- COPS6 | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as COSV57996596, COSV57997598; called by muse, mutect2
- CPNE1 | c.890G>C p.G297A (on ENST00000352393; = p.G302A on NM_003915.5) | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58291721; called by muse, varscan2
- CTSB | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775321729, COSV61540736; called by muse, varscan2
- CXXC1 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 11/181 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV53274668; called by muse, mutect2
- CYTH4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757325443, COSV50632594; called by muse, mutect2, varscan2
- DARS2 | c.1223G>T p.R408I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV53407134; called by muse, mutect2, varscan2
- DCSTAMP | c.768A>C p.E256D | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs749355177, COSV52577839; called by muse, mutect2, varscan2
- DDX58 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV65883027, COSV65883275, COSV65883563; called by muse, mutect2, varscan2
- DHTKD1 | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 161/353 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53803790, COSV53804503; called by muse, mutect2, varscan2
- DIP2C | c.1200C>G p.F400L | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs1398263158, COSV55159123; called by muse, mutect2, varscan2
- DISP3 | c.3579C>G p.I1193M | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53827976; called by muse, mutect2, varscan2
- DLX5 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99033600; called by muse, mutect2
- DNAAF2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100023733, COSV53567860; called by muse, mutect2
- DNAH2 | c.7533G>T p.W2511C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.484); catalogued as COSV66719921; called by muse, mutect2, varscan2
- DNAH3 | c.7983C>G p.F2661L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54523838; called by muse, mutect2, varscan2
- DNAJC6 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV54775326; called by muse, mutect2, varscan2
- DNHD1 | c.13360C>T p.Q4454* | Nonsense Mutation (SNP) | VAF 11/105 reads (10%) | catalogued as COSV99599303; called by muse, mutect2, varscan2
- DNM1 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV57851786; called by muse, mutect2, varscan2
- DNTTIP2 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV63284054; called by muse, mutect2, varscan2
- DPY19L2 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV100116427; called by muse, mutect2, varscan2
- DRICH1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1176314800, COSV58503903; called by muse, mutect2, varscan2
- DSC3 | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV64573086; called by muse, mutect2, varscan2
- DSG1 | c.1957G>C p.G653R | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as COSV57135579; called by muse, mutect2, varscan2
- DTL | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1312899708, COSV65342419; called by muse, mutect2, varscan2
- DYNC1H1 | c.5339C>A p.S1780Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV64137189; called by muse, mutect2, varscan2
- DYNC1H1 | c.12781G>C p.D4261H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794271; called by muse, mutect2
- EFCAB5 | c.2795C>G p.S932* | Nonsense Mutation (SNP) | VAF 6/105 reads (6%) | catalogued as COSV100299672; called by muse, mutect2
- EFR3A | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1212454955, COSV54457589; called by muse, mutect2, varscan2
- EIF2B4 | c.778A>G p.M260V (on ENST00000347454 / NM_001034116.2; = p.M259V on NM_015636.3) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs752440296, COSV52007923; called by muse, mutect2, varscan2
- EIF4A2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV56215421, COSV56217101; called by muse, mutect2, varscan2
- ENPP1 | c.2627C>T p.S876L | Missense Mutation (SNP) | VAF 37/54 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs764466020, COSV62932471; called by muse, mutect2, varscan2
- ERC2 | c.558G>C p.W186C | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55623578; called by muse, mutect2, varscan2
- ESPL1 | c.5554C>G p.Q1852E | Missense Mutation (SNP) | VAF 84/269 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV54475981; called by muse, varscan2
- ETV6 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs1471948383, COSV101122495, COSV67150283; called by muse, mutect2, varscan2
- EXOC6 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV53324853; called by muse, mutect2, varscan2
- EZH2 | c.2001C>G p.F667L (on ENST00000460911 / NM_001203247.2; = p.F672L on NM_004456.5) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57453519, COSV57455265; called by muse, mutect2, varscan2
- FAM104B | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV59776997; called by muse, mutect2, varscan2
- FAM155A | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV65562925; called by muse, mutect2, varscan2
- FAM71A | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as COSV54236692; called by muse, mutect2, varscan2
- FAM71E1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs762678353, COSV100618562, COSV58542323; called by muse, mutect2, varscan2
- FANCI | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772954096, COSV55527435; called by muse, mutect2, varscan2
- FASTKD3 | c.1463T>G p.L488W | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV52944014; called by muse, mutect2, varscan2
- FAT2 | c.4423C>G p.Q1475E | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1240773414, COSV55820173; called by muse, mutect2
- FBXL2 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV52138963; called by muse, mutect2
- FLRT3 | c.904C>G p.L302V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.557); catalogued as COSV53987635; called by muse, mutect2
- FLT1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV56728647; called by muse, mutect2
- FN1 | c.6853G>A p.E2285K (on ENST00000359671 / NM_001365524.2; = p.E2254K on NM_002026.4) | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60553541; called by muse, mutect2, varscan2
- FNDC7 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54753347; called by muse, mutect2
- FOXP4 | c.1816G>A p.D606N (on ENST00000307972 / NM_001012426.1; = p.D593N on NM_138457.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV57220167; called by muse, mutect2, varscan2
- FREM2 | c.3868A>T p.K1290* | Nonsense Mutation (SNP) | VAF 93/235 reads (40%) | catalogued as COSV99746336; called by muse, mutect2, varscan2
- FRS2 | c.1431G>C p.E477D | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.157); catalogued as COSV54726096; called by muse, mutect2
- FRY | c.5093C>G p.S1698C | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as COSV66570531; called by muse, mutect2, varscan2
- FUT8 | c.809C>T p.S270F (on ENST00000360689 / NM_001371534.1; = p.S107F on NM_004480.4) | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV61284750; called by muse, mutect2, varscan2
- FZR1 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV100553343; called by muse, mutect2, varscan2
- GAS7 | c.1423G>C p.E475Q (on ENST00000432992 / NM_201433.2; = p.E335Q on NM_003644.3) | Missense Mutation (SNP) | VAF 86/102 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as COSV60436838; called by muse, mutect2, varscan2
- GMIP | c.2803G>C p.E935Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV52556365; called by muse, mutect2, varscan2
- GOLGA1 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV101002617, COSV65229640; called by muse, mutect2
- GOLGA2 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.311); catalogued as COSV68597221; called by muse, mutect2
- GPC6 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV65512594; called by muse, mutect2, varscan2
- GRIK3 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs775379362, COSV66139441; called by muse, mutect2
- GRIN2A | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV58034175; called by muse, mutect2, varscan2
- GRK6 | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as rs1276585111, COSV100586811; called by muse, mutect2
- GUCY1A2 | c.547C>T p.H183Y | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV56487187; called by muse, mutect2, varscan2
- HAL | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs373688754; called by muse, mutect2, varscan2
- HDGFL3 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV55206079; called by muse, mutect2, varscan2
- HIRA | c.2915G>T p.S972I | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV54275136; called by muse, mutect2
- HKDC1 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100664331; called by muse, mutect2
- HMCN1 | c.8287C>T p.Q2763* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV54934885, COSV99623070; called by muse, mutect2, varscan2
- HMCN1 | c.8641G>T p.E2881* | Nonsense Mutation (SNP) | VAF 33/188 reads (18%) | catalogued as COSV99623073; called by muse, mutect2, varscan2
- HSPA1L | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV65149056; called by muse, varscan2
- HSPA1L | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65149058; called by muse, varscan2
- HTR1D | c.357C>G p.I119M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.936); catalogued as COSV58448179; called by muse, mutect2, varscan2
- IDH3B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV66483274; called by muse, mutect2, varscan2
- IFNGR2 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99274496; called by muse, mutect2, varscan2
- IGF1R | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1335469497, COSV51290002; called by muse, mutect2
- INPPL1 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV53355725, COSV53356922; called by muse, mutect2, varscan2
- INSC | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV65410727; called by muse, mutect2
- IRX4 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs1434287748, COSV51474963, COSV99180755; called by muse, mutect2, varscan2
- ITGAM | c.1733C>T p.S578F (on ENST00000648685 / NM_001145808.2; = p.S577F on NM_000632.4) | Missense Mutation (SNP) | VAF 70/128 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV54937366; called by muse, mutect2, varscan2
- KATNIP | c.4743G>A p.M1581I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV55181125; called by muse, mutect2, varscan2
- KCNB2 | c.2373G>C p.Q791H | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV101578938, COSV73050386; called by muse, mutect2, varscan2
- KCNK16 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 100/199 reads (50%) | catalogued as COSV100949048, COSV64678629; called by muse, mutect2, varscan2
- KCNN3 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV55217610; called by muse, mutect2, varscan2
- KHK | c.83C>G p.S28W | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99565671; called by muse, mutect2
- KIAA1191 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.42); catalogued as COSV53798951; called by muse, mutect2, varscan2
- KIF23 | c.1319G>C p.R440T | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52979971; called by muse, mutect2, varscan2
- LCT | c.5416G>A p.E1806K | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV51550036; called by muse, mutect2, varscan2
- LILRB1 | c.2077A>T p.S693C (on ENST00000427581; = p.S642C on NM_006669.6) | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61118364; called by muse, mutect2
- LIN28A | c.483C>G p.C161W | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54261944; called by muse, mutect2
- LIPH | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV56184111; called by muse, mutect2, varscan2
- LMNB2 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV57588141; called by muse, mutect2
- LRP1B | c.6946G>C p.E2316Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV67222505; called by muse, mutect2, varscan2
- LSM14A | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70885134; called by muse, mutect2, varscan2
- MACF1 | c.15551C>A p.S5184Y (on ENST00000372915; = p.S3117Y on NM_012090.5) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV57122247; called by muse, mutect2, varscan2
- MAGI2 | c.1226-1G>A p.X409_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV62661416; called by muse, mutect2
- MAP3K9 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV67119895, COSV67121431, COSV67122863; called by muse, mutect2, varscan2
- MARK3 | c.2014C>A p.P672T (on ENST00000429436 / NM_001128918.3; = p.P648T on NM_002376.6) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53510472, COSV53511037; called by muse, mutect2, varscan2
- MBLAC1 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as COSV99498738; called by muse, mutect2, varscan2
- MC4R | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV55352152; called by muse, mutect2
- MCAM | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV50680624; called by muse, mutect2, varscan2
- MED23 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV63432701; called by muse, mutect2, varscan2
- MEF2B | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs368120349, COSV50766370; called by muse, mutect2, varscan2
- METTL14 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 69/89 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310629; called by muse, mutect2, varscan2
- MIA2 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV54488928, COSV99697192; called by muse, mutect2
- MKI67 | c.5005G>C p.D1669H | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64074487; called by muse, varscan2
- MMEL1 | c.2109G>C p.Q703H | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.726); catalogued as COSV56521658; called by muse, mutect2, varscan2
- MMP9 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1481207494, COSV63434037, COSV63434115; called by muse, mutect2
- MPP3 | c.1047G>C p.E349D | Missense Mutation (SNP) | VAF 122/146 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV68198223; called by muse, mutect2, varscan2
- MS4A12 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV50014192, COSV50014544; called by muse, mutect2
- MTG2 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.131); catalogued as COSV63693893; called by muse, mutect2, varscan2
- MTMR3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60304604; called by muse, mutect2, varscan2
- MTOR | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.974); catalogued as rs762176419, COSV63871869; called by muse, mutect2, varscan2
- MUC17 | c.7369C>G p.P2457A | Missense Mutation (SNP) | VAF 55/541 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV60281565, COSV60289466; called by muse, mutect2, varscan2
- MYH15 | c.1134G>C p.Q378H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56310687; called by muse, mutect2
- MYOM3 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58394321; called by muse, mutect2, varscan2
- NAGLU | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs756138287, COSV56794835; called by muse, mutect2, varscan2
- NAT1 | c.481C>G p.L161V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV56985275; called by muse, mutect2, varscan2
- NAV2 | c.6163G>A p.D2055N (on ENST00000396087 / NM_001244963.2; = p.D1996N on NM_145117.5) | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1240265876, COSV60659578; called by muse, mutect2, varscan2
- NCKAP5 | c.2441C>G p.S814* | Nonsense Mutation (SNP) | VAF 129/177 reads (73%) | catalogued as COSV100489638; called by muse, mutect2, varscan2
- NIF3L1 | c.1120C>G p.L374V (on ENST00000409020 / NM_001369444.1; = p.L347V on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100677495, COSV62900232; called by muse, mutect2, varscan2
- NINL | c.2810G>T p.G937V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV54002901; called by muse, mutect2, varscan2
- NOL4L | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 99/253 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV62889446; called by muse, mutect2, varscan2
- NRG2 | c.1481C>G p.S494C | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56832636, COSV56833381; called by muse, mutect2, varscan2
- NSD1 | c.2919G>C p.Q973H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV61776582; called by muse, mutect2, varscan2
- NSD1 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as rs1348023231, COSV61776619; ClinVar: uncertain significance; called by muse, mutect2
- NT5C1A | c.499C>G p.H167D | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.281); catalogued as COSV52494586; called by muse, mutect2, varscan2
- NUDT9 | c.999G>C p.E333D | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56196744; called by muse, mutect2
- NUP205 | c.3841C>T p.H1281Y | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV53659503; called by muse, mutect2, varscan2
- NUTM2A | c.556C>A p.L186M | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67741954; called by muse, mutect2, varscan2
- NXF3 | c.675A>T p.R225S | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV67703603; called by muse, mutect2, varscan2
- OGDHL | c.2759C>G p.S920C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1415243995, COSV65102624; called by muse, mutect2, varscan2
- OPTN | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs747128537, COSV53810912; called by muse, mutect2
- OR13C9 | c.624G>C p.L208F | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV52241992; called by muse, mutect2, varscan2
- OR13H1 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58547665; called by muse, mutect2, varscan2
- OR1Q1 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1227490619, COSV52917669; called by muse, mutect2, varscan2
- OR52N1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV57693388; called by muse, mutect2
- OR5B17 | c.602C>G p.S201* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV100641841, COSV62160566; called by muse, mutect2, varscan2
- OR5K3 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as rs376406284, COSV67350601; called by muse, mutect2
- OR8B4 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.014); catalogued as COSV62069799; called by muse, mutect2
- OR9I1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV56926117; called by muse, mutect2, varscan2
- OXSM | c.733C>G p.L245V | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs372644482, COSV55001642; called by muse, mutect2, varscan2
- P4HTM | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59087086; called by muse, mutect2
- PAICS | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | PolyPhen benign (0.085); catalogued as COSV51708739; called by muse, mutect2
- PCDHA2 | c.2268G>T p.Q756H | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV65367267; called by muse, mutect2, varscan2
- PCDHB9 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs372037482; called by muse, mutect2
- PCP4 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60787330; called by muse, mutect2, varscan2
- PDE10A | c.2278A>T p.S760C | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV63097033; called by muse, mutect2, varscan2
- PDGFC | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.21); PolyPhen benign (0.339); catalogued as COSV56848885; called by muse, mutect2, varscan2
- PGA3 | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV57711714; called by muse, mutect2, varscan2
- PIK3C2A | c.4954C>G p.L1652V | Missense Mutation (SNP) | VAF 128/315 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV56403030; called by muse, mutect2, varscan2
- PITRM1 | c.531C>G p.F177L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV99828165; called by muse, mutect2, varscan2
- PIWIL3 | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV59995663; called by muse, mutect2, varscan2
- PLBD1 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 67/181 reads (37%) | catalogued as COSV99554184; called by muse, mutect2, varscan2
- PLCL2 | c.1321C>T p.H441Y (on ENST00000615277 / NM_001144382.2; = p.H315Y on NM_015184.5) | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.534); catalogued as COSV67622272, COSV67623934; called by muse, mutect2, varscan2
- PLEKHS1 | c.784G>A p.E262K (on ENST00000369310 / NM_182601.1; = p.E268K on NM_024889.5) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV63055093; called by muse, mutect2, varscan2
- PLXNA4 | c.674C>G p.S225W | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58128167; called by muse, mutect2, varscan2
- PLXNB2 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV100833813; called by muse, mutect2
- PNOC | c.126+2T>G p.X42_splice | Splice Site (SNP) | VAF 38/90 reads (42%) | catalogued as COSV57283613; called by muse, mutect2, varscan2
- POU6F2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV68869291; called by muse, mutect2, varscan2
- PPARGC1A | c.1938G>C p.K646N | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV53527786; called by muse, mutect2
- PPHLN1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV56731477; called by muse, mutect2, varscan2
- PRC1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as COSV62695391; called by muse, mutect2
- PRDM9 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as COSV57004487; called by muse, mutect2, varscan2
- PRKD1 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV59569590; called by muse, mutect2, varscan2
- PROS1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62398483, COSV62399192; called by muse, mutect2, varscan2
- PRPF4 | c.478G>C p.E160Q (on ENST00000374198 / NM_001322267.2; = p.E161Q on NM_004697.5) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.035); catalogued as COSV65252726; called by muse, mutect2, varscan2
- PSD3 | c.2688_2689insT p.A897Cfs*20 (on ENST00000440756; = p.A896Cfs*20 on NM_015310.4) | Frame Shift Ins (INS) | VAF 60/164 reads (37%) | catalogued as COSV54071936; called by mutect2, pindel, varscan2
- PSD4 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55527016; called by muse, mutect2, varscan2
- PSMA4 | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV50384502; called by muse, mutect2
- PSMB9 | c.393A>G p.V131= | Splice Region (SNP) | VAF 67/127 reads (53%) | catalogued as rs780420893, COSV62754585; called by muse, mutect2, varscan2
- PTCD2 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as rs755116275, COSV54651361, COSV54654034, COSV99781895; called by muse, mutect2, varscan2
- PTCH2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV64711144; called by muse, mutect2, varscan2
- PTPN5 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs780842182, COSV62125638; called by muse, mutect2, varscan2
- PTPRB | c.5019G>T p.Q1673H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV54238433, COSV54241453; called by muse, mutect2
- PUSL1 | c.321C>T p.I107= | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as COSV60088367; called by muse, mutect2, varscan2
- PXDN | c.2151C>G p.I717M | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53234455, COSV53238410; called by muse, mutect2, varscan2
- RAI1 | c.4649C>G p.S1550C | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as CD056839, COSV55391309, COSV55393309; called by muse, mutect2
- RALGAPA2 | c.5230G>A p.E1744K | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754496994, COSV52498348; called by muse, mutect2, varscan2
- RALGPS2 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61337178; called by muse, mutect2
- RASA3 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV61867604; called by muse, mutect2, varscan2
- RBM34 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV64012772; called by muse, mutect2, varscan2
- RBM6 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV56483053; called by muse, mutect2, varscan2
- RBM8A | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.166); catalogued as rs1180452185, COSV57162393; called by muse, mutect2, varscan2
- RBM8A | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as COSV57162387; called by muse, mutect2, varscan2
- RBM8A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV57162385; called by muse, varscan2
- REPS1 | c.1781C>T p.S594L (on ENST00000450536 / NM_001286611.2; = p.S593L on NM_031922.4) | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV57810914; called by muse, mutect2, varscan2
- RET | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.958); catalogued as rs3026759, COSV60695006; called by muse, mutect2, varscan2
- RFC1 | c.2976G>T p.R992S (on ENST00000381897 / NM_001363496.2; = p.R991S on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV62899709; called by muse, mutect2, varscan2
- RGS14 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV68771272; called by muse, mutect2
- RIMS1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as COSV53457314, COSV53470212; called by muse, mutect2, varscan2
- RNF150 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 83/113 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60790952; called by muse, mutect2, varscan2
- RNF19A | c.451C>G p.H151D | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.3); catalogued as COSV61993290; called by muse, mutect2, varscan2
- RNF19A | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs923175764, COSV61992127; called by muse, mutect2, varscan2
- ROBO2 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV59912436; called by muse, mutect2
- ROS1 | c.5809C>A p.L1937I | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63854945, COSV63855519; called by muse, mutect2, varscan2
- RP1L1 | c.6526G>A p.E2176K | Missense Mutation (SNP) | VAF 191/469 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.861); catalogued as COSV66755386; called by muse, mutect2, varscan2
- RSF1 | c.4149G>C p.L1383F | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs776494197, COSV57840191; called by muse, mutect2, varscan2
- RSPO2 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52644630, COSV99410174; called by muse, mutect2, varscan2
- RWDD1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV63972483; called by muse, mutect2, varscan2
- SACS | c.10037C>A p.P3346H | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV66540245; called by muse, mutect2
- SAMD15 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV53626390; called by muse, mutect2, varscan2
- SAMD9 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV66075383; called by muse, mutect2, varscan2
- SART1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV56711700, COSV56712123; called by muse, mutect2, varscan2
- SCAF4 | c.2271C>G p.H757Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.346); catalogued as COSV54587314; called by muse, mutect2, varscan2
- SCFD1 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV61724073; called by muse, mutect2, varscan2
- SDAD1 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 83/343 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV62402855; called by muse, mutect2, varscan2
- SEC31A | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV58874963; called by muse, mutect2
- SELENOV | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374699082; called by muse, mutect2, varscan2
- SELP | c.42G>C p.Q14H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55252398; called by muse, mutect2, varscan2
- SEMA4A | c.1721C>G p.S574C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV61772766, COSV61774356; called by muse, mutect2, varscan2
- SEMA4A | c.2149C>T p.Q717* | Nonsense Mutation (SNP) | VAF 6/106 reads (6%) | catalogued as COSV100740399; called by muse, mutect2
- SERPINC1 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 54/157 reads (34%) | catalogued as COSV100874985; called by muse, mutect2, varscan2
- SETBP1 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV56322574; called by muse, mutect2, varscan2
- SETD9 | c.778C>A p.L260I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.695); catalogued as COSV53650395; called by muse, mutect2, varscan2
- SKIL | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV52059935; called by muse, mutect2
- SLC17A3 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.401); catalogued as rs1384180198, COSV100399210, COSV57760101; called by muse, mutect2
- SLC19A2 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.216); catalogued as COSV52547360; called by muse, varscan2
- SLC25A22 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57192898; called by muse, mutect2, varscan2
- SLC25A25 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV66090978; called by muse, mutect2
- SLC26A1 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56103407; called by muse, mutect2
- SLC26A6 | c.2027G>A p.G676D | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs754009839, COSV56572165; called by muse, varscan2
- SLC2A5 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs754707926, COSV66236528; called by muse, mutect2, varscan2
- SLC44A2 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100212928; called by muse, mutect2
- SLC45A1 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57095685; called by muse, mutect2, varscan2
- SLC5A2 | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV57891728; called by muse, mutect2, varscan2
- SLC5A4 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs770695472, COSV56670608; called by muse, mutect2, varscan2
- SLC8B1 | c.1491C>T p.F497= | Splice Region (SNP) | VAF 6/82 reads (7%) | catalogued as COSV52528232; called by muse, mutect2
- SLCO4C1 | c.286C>G p.Q96E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV60513857, COSV60515972; called by muse, mutect2
- SMAD4 | c.1280A>G p.H427R | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs1555686619, COSV61688619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD6 | c.1010G>T p.W337L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56594991; called by muse, varscan2
- SMC2 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.392); catalogued as COSV99658185; called by muse, mutect2
- SPATA17 | c.740T>C p.I247T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs540164939, COSV65122087; called by muse, mutect2, varscan2
- SPRR1A | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as COSV61081176, COSV61081572; called by muse, mutect2
- SQSTM1 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52973132; called by muse, mutect2, varscan2
- SRGAP2 | c.2624C>A p.S875Y (on ENST00000624873 / NM_001170637.4; = p.S876Y on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV55337789; called by muse, mutect2, varscan2
- SRPK1 | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60412941; called by muse, mutect2, varscan2
- SRPX | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.562); catalogued as COSV100655863, COSV59438850; called by muse, mutect2, varscan2
- STAB1 | c.5500-2A>T p.X1834_splice | Splice Site (SNP) | VAF 6/61 reads (10%) | catalogued as COSV58736607; called by muse, mutect2, varscan2
- STAT1 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100738403, COSV63115791; called by muse, mutect2, varscan2
- STK39 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs773594176, COSV63597218; called by muse, mutect2, varscan2
- STON2 | c.2158C>A p.L720M (on ENST00000649389 / NM_001366849.2; = p.L663M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV50845063; called by muse, mutect2, varscan2
- SUSD1 | c.1536C>G p.I512M | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs762068940, COSV62583688; called by muse, mutect2, varscan2
- SWAP70 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100013443; called by muse, mutect2, varscan2
- SYNE1 | c.22843C>A p.L7615M (on ENST00000367255 / NM_182961.4; = p.L7544M on NM_033071.3) | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV54974775; called by muse, mutect2, varscan2
- SYNE2 | c.12454G>T p.E4152* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100646453; called by mutect2, varscan2
- SYNE2 | c.12607G>A p.E4203K | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.156); catalogued as COSV59951719; called by muse, mutect2
- SYNPO2 | c.1260G>T p.E420D | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV61111272; called by muse, mutect2, varscan2
- TAF1 | c.1138G>A p.E380K (on ENST00000373790 / NM_138923.4; = p.E401K on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/91 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1429072062, COSV52113952; called by muse, mutect2, varscan2
- TAOK3 | c.2367G>C p.E789D | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as COSV66825937; called by muse, mutect2, varscan2
- TAOK3 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV66825939; called by muse, mutect2
- TAOK3 | c.1295G>A p.R432K | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV66825784; called by muse, mutect2
- TAS2R30 | c.411G>C p.L137F | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.525); catalogued as COSV67856159; called by muse, varscan2
- TBCCD1 | c.1279G>C p.E427Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV58662238; called by muse, mutect2, varscan2
- TEC | c.651G>A p.W217* | Nonsense Mutation (SNP) | VAF 46/109 reads (42%) | catalogued as COSV101202531; called by muse, varscan2
- TECPR2 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.036); catalogued as COSV63970764, COSV63972172; called by muse, mutect2, varscan2
- TFEC | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1219945713, COSV55400891; called by muse, mutect2, varscan2
- TGIF2LX | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.348); catalogued as COSV52213800; called by muse, mutect2, varscan2
- THG1L | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV51452918; called by muse, mutect2, varscan2
- TINF2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV57469075; called by muse, mutect2, varscan2
- TINF2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 44/252 reads (17%) | catalogued as COSV99945228; called by muse, mutect2, varscan2
- TMEM245 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 28/221 reads (13%) | catalogued as rs1378977012, COSV101002153; called by muse, mutect2, varscan2
- TMEM51 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.352); catalogued as COSV65691051; called by muse, mutect2, varscan2
- TMEM59 | c.597G>C p.L199F | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as COSV99328936; called by muse, mutect2
- TNC | c.5972G>A p.G1991E | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421059384, COSV60785205; called by muse, mutect2, varscan2
- TNKS1BP1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64101138, COSV64102430; called by muse, mutect2, varscan2
- TRAV41 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as rs1403885773; called by muse, mutect2, varscan2
- TRHDE | c.1435C>G p.P479A | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527918088, COSV53845304; called by muse, mutect2
- TRRAP | c.8635G>C p.E2879Q (on ENST00000359863 / NM_001244580.1; = p.E2861Q on NM_003496.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV62844911; called by muse, mutect2, varscan2
- TSHR | c.18G>C p.L6F | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.648); catalogued as COSV53320513, COSV53333403; called by muse, mutect2, varscan2
- TSHR | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53320539; called by muse, mutect2, varscan2
- TSPYL2 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV64921134; called by muse, mutect2, varscan2
- TSPYL5 | c.888C>G p.F296L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV59071732; called by muse, mutect2, varscan2
- TTN | c.5188G>T p.G1730C (on ENST00000591111; = p.G1684C on NM_003319.4) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | PolyPhen probably damaging (1); catalogued as COSV100591208; called by muse, mutect2
- TUT1 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53470116; called by muse, mutect2
- UBE2A | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100660458; called by muse, mutect2, varscan2
- UBN1 | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52168281; called by muse, mutect2, varscan2
- UFL1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65149894, COSV65150390; called by muse, mutect2, varscan2
- UGT3A1 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as COSV57098384, COSV57099132; called by muse, mutect2, varscan2
- UNC13B | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV101036102; called by muse, mutect2, varscan2
- UNC13C | c.1076T>A p.F359Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.196); catalogued as COSV52875391; called by muse, mutect2, varscan2
- UNC13D | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 77/91 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52884769; called by muse, mutect2, varscan2
- UNC79 | c.2503A>T p.I835L (on ENST00000393151 / NM_001346218.2; = p.I658L on NM_020818.5) | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.811); catalogued as COSV56389080; called by muse, mutect2
- USP13 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55865903; called by muse, mutect2, varscan2
- USP18 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1569209130, COSV53173526; called by muse, mutect2, varscan2
- USP21 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV57088866; called by muse, mutect2
- USP24 | c.2794G>A p.E932K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53768097; called by muse, mutect2, varscan2
- USP33 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62469558; called by muse, mutect2, varscan2
- USP48 | c.2239C>A p.Q747K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57610394; called by muse, mutect2, varscan2
- USP48 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.134); catalogued as COSV57610410; called by muse, mutect2
- USP54 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60442846; called by muse, mutect2, varscan2
- VGF | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.198); catalogued as COSV50801174; called by muse, mutect2, varscan2
- VIRMA | c.4609C>G p.Q1537E | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.932); catalogued as COSV52585277, COSV52588120; called by muse, mutect2
- VPS13C | c.8023C>T p.L2675F (on ENST00000644861 / NM_020821.3; = p.L2632F on NM_017684.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV51131040, COSV51186488; called by muse, mutect2, varscan2
- VPS33A | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57356269, COSV57357108; called by muse, mutect2, varscan2
- WDFY3 | c.6208G>C p.D2070H | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV55701507; called by muse, mutect2, varscan2
- WFDC8 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV51489756, COSV51490259; called by muse, mutect2, varscan2
- WIZ | c.2545G>A p.E849K (on ENST00000673675 / NM_001371589.1; = p.E112K on NM_021241.3) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV54607803; called by muse, mutect2, varscan2
- WWC3 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV66503522; called by muse, mutect2, varscan2
- XAB2 | c.2164G>C p.E722Q | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50335336, COSV50335450; called by muse, mutect2
- XRCC4 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV56538380, COSV56542709; called by muse, mutect2, varscan2
- XRN2 | c.624C>G p.I208M | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65869630; called by muse, mutect2, varscan2
- YES1 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100099122, COSV100099926, COSV58852840; called by muse, mutect2
- YY1AP1 | c.433G>A p.E145K (on ENST00000295566 / NM_139118.2; = p.E68K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763431851, COSV55121496; called by muse, mutect2, varscan2
- ZBTB49 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61925123; called by muse, mutect2, varscan2
- ZFAND4 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV60859170; called by muse, mutect2, varscan2
- ZFP57 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 136/281 reads (48%) | catalogued as COSV100971785; called by muse, mutect2, varscan2
- ZFYVE26 | c.3799G>A p.D1267N | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV61328739; called by muse, mutect2
- ZFYVE28 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as COSV52111391; called by muse, mutect2, varscan2
- ZNF124 | c.963G>C p.Q321H (on ENST00000543802 / NM_001297568.1; = p.Q259H on NM_003431.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV61507356, COSV61507864; called by muse, mutect2, varscan2
- ZNF254 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV61641678, COSV61642642; called by muse, mutect2, varscan2
- ZNF324B | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as COSV60740976; called by muse, mutect2, varscan2
- ZNF415 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1249570477, COSV54701467; called by muse, mutect2, varscan2
- ZNF423 | c.3016C>T p.Q1006* (on ENST00000563137 / NM_001379286.1; = p.Q998* on NM_015069.4) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as rs752989483, COSV99279386; called by muse, mutect2, varscan2
- ZNF441 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs761219801, COSV63539911; called by muse, mutect2, varscan2
- ZNF443 | c.1217C>G p.S406* | Nonsense Mutation (SNP) | VAF 43/153 reads (28%) | catalogued as COSV100041869; called by muse, mutect2, varscan2
- ZNF470 | c.1912C>G p.L638V | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.026); catalogued as COSV57968518; called by muse, mutect2
- ZNF483 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58515704; called by muse, mutect2, varscan2
- ZNF518B | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58722312, COSV58722747; called by muse, mutect2
- ZNF530 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.62); catalogued as COSV60531659; called by muse, mutect2
- ZNF559 | c.602G>A p.R201K | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV57835380, COSV57835666; called by muse, mutect2
- ZNF568 | c.1455G>C p.Q485H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61741577; called by muse, mutect2
- ZNF577 | c.1049G>C p.G350A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV56816042; called by muse, mutect2, varscan2
- ZNF578 | c.1737G>C p.L579F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.85); catalogued as COSV69736546; called by muse, mutect2, varscan2
- ZNF780B | c.1812G>C p.Q604H | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55464477; called by muse, mutect2, varscan2
- ZNF804A | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100165987, COSV56440824; called by muse, mutect2, varscan2
- ZNF99 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV68055831; called by muse, mutect2, varscan2
- ZSCAN22 | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as rs953033778, COSV61639131; called by muse, mutect2, varscan2
- ZSWIM4 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54321943; called by muse, mutect2
- GABRR2 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- IGLV5-52 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2
- LIME1 | c.805_806dup p.C270Rfs*15 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- MTF2 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- POTEA | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.202); called by muse, mutect2
- PTPRC | c.2719C>T p.Q907* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SUPT20HL1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2
- SYNE2 | c.19221_19238del p.E6407_V6412del | In Frame Del (DEL) | VAF 14/155 reads (9%) | called by mutect2, pindel
- TRAJ19 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 16/293 reads (5%) | called by muse, mutect2
- TRAV13-1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2
- U2SURP | c.2276C>G p.S759* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- ABCC3 | c.3918G>C p.L1306= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV53322228, COSV53325880; called by muse, mutect2
- ABHD12 | c.978C>G p.L326= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV59285274, COSV59286032, COSV59286250; called by muse, mutect2, varscan2
- ACHE | c.291G>A p.Q97= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV53817708; called by muse, mutect2
- ACOT8 | c.753C>T p.F251= | Silent (SNP) | VAF 38/62 reads (61%) | catalogued as COSV54169589; called by muse, mutect2, varscan2
- ACTR3B | c.984C>T p.F328= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV55449310; called by muse, mutect2
- ADCY10 | c.4725C>T p.I1575= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV63241004; called by muse, mutect2
- ADH1B | c.441C>T p.F147= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV59296534; called by muse, mutect2
- AGMO | c.939C>T p.L313= | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV61113091; called by muse, mutect2
- ALOX12B | c.2082G>C p.L694= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV59871070, COSV59873030; called by muse, mutect2, varscan2
- ANO8 | c.651G>A p.L217= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV50178624; called by muse, mutect2
- ARHGAP28 | c.1794G>A p.K598= (on ENST00000383472 / NM_001366230.1; = p.K439= on NM_001010000.3) | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as COSV51637774; called by muse, mutect2, varscan2
- ARHGEF16 | c.1206G>A p.L402= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs376132226; called by muse, mutect2, varscan2
- BAG6 | c.3324G>C p.V1108= (on ENST00000676571; = p.V1061= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV99276277; called by muse, mutect2
- BIVM-ERCC5 | c.1407C>T p.F469= | Silent (SNP) | VAF 58/208 reads (28%) | catalogued as COSV57279718; called by muse, mutect2, varscan2
- CATSPER1 | c.2160G>A p.L720= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV56409072; called by muse, mutect2, varscan2
- CCN5 | c.231C>G p.V77= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99509132; called by muse, mutect2, varscan2
- CCNO | c.447C>G p.L149= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV57004642; called by muse, mutect2, varscan2
- CCR3 | c.249C>T p.F83= | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as rs774437865, COSV62463443; called by muse, mutect2, varscan2
- CD22 | c.357G>C p.L119= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV50053491; called by muse, mutect2, varscan2
- CDH8 | c.2367C>G p.L789= | Silent (SNP) | VAF 44/58 reads (76%) | catalogued as rs1263717105, COSV100183961, COSV54868623; called by muse, mutect2, varscan2
- CEBPE | c.702G>A p.Q234= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as rs753381359, COSV52829855; called by muse, mutect2
- CELSR2 | c.7818C>T p.F2606= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV54772322; called by muse, mutect2
- CEP350 | c.5319G>T p.L1773= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV62602908; called by muse, mutect2, varscan2
- CHST1 | c.312C>T p.F104= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV57323693; called by muse, mutect2
- CHST5 | c.351G>A p.L117= | Silent (SNP) | VAF 64/80 reads (80%) | catalogued as COSV60339275; called by muse, mutect2, varscan2
- CLCA4 | c.1908G>A p.Q636= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV55368392, COSV99760463; called by muse, mutect2, varscan2
- CNTN5 | c.540G>C p.G180= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as COSV54312441; called by muse, mutect2
- COPB1 | c.528G>A p.L176= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV51447981; called by muse, mutect2, varscan2
- CPNE1 | c.924G>A p.L308= (on ENST00000352393; = p.L313= on NM_003915.5) | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV58291709; called by muse, varscan2
- DCAF12L1 | c.357G>A p.T119= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100948153, COSV64421813; called by muse, mutect2, varscan2
- DCAF8L1 | c.1248C>T p.L416= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as COSV71595303; called by muse, mutect2, varscan2
- DCUN1D3 | c.714C>T p.I238= | Silent (SNP) | VAF 45/65 reads (69%) | catalogued as COSV60953429; called by muse, mutect2, varscan2
- DENND4C | c.4134G>A p.L1378= (on ENST00000434457 / NM_001330640.2; = p.L1329= on NM_017925.7) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV63008897; called by muse, mutect2, varscan2
- DICER1 | c.4749C>T p.L1583= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as rs767814647, COSV58620270; called by muse, mutect2, varscan2
- DLGAP2 | c.1944G>A p.Q648= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs757117649, COSV101420989; called by muse, mutect2
- DNAJB2 | c.150C>T p.A50= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs779463890, COSV60676694; called by muse, mutect2, varscan2
- DNM2 | c.2085G>A p.L695= (on ENST00000355667 / NM_001005360.3; = p.L691= on NM_004945.3) | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV53035714; called by muse, mutect2
- DRG2 | c.750G>A p.Q250= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV56728308, COSV56728652; called by mutect2, varscan2
- DSN1 | c.360C>G p.L120= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV65519230; called by muse, mutect2
- DTX2 | c.384C>T p.V128= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV56860846; called by muse, mutect2, varscan2
- EPB41 | c.1261C>T p.L421= (on ENST00000343067 / NM_001166005.2; = p.L212= on NM_004437.4) | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV58047015; called by muse, mutect2
- EPHB1 | c.576C>T p.F192= | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as COSV67662036; called by muse, mutect2
- EPHX1 | c.942G>A p.L314= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV55301008; called by muse, mutect2, varscan2
- ERI1 | c.954C>T p.I318= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV51571354; called by muse, mutect2, varscan2
- ERV3-1 | c.672C>G p.V224= | Silent (SNP) | VAF 59/227 reads (26%) | catalogued as COSV51427815; called by muse, mutect2, varscan2
- ESPL1 | c.5676C>G p.V1892= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV54475984; called by muse, mutect2, varscan2
- ESRP1 | c.118C>T p.L40= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV64409971; called by muse, mutect2, varscan2
- F2R | c.879C>A p.I293= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV59929159, COSV59929409, COSV59930196; called by muse, mutect2, varscan2
- FBXO22 | c.927C>T p.L309= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV57617568; called by muse, mutect2, varscan2
- FBXO45 | c.825G>A p.V275= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV61146535; called by muse, mutect2, varscan2
- FEM1B | c.906T>C p.Y302= | Silent (SNP) | VAF 12/140 reads (9%) | catalogued as rs1343621429, COSV60988550; called by muse, mutect2
- FYCO1 | c.3021G>C p.L1007= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV56116158; called by muse, mutect2, varscan2
- FZD10 | c.897C>T p.V299= | Silent (SNP) | VAF 66/124 reads (53%) | catalogued as COSV57473671; called by muse, mutect2, varscan2
- GPR50 | c.210C>T p.L70= | Silent (SNP) | VAF 257/299 reads (86%) | catalogued as COSV54439291; called by muse, mutect2, varscan2
- GRIA4 | c.21G>A p.Q7= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV56884171, COSV56897286, COSV56922020; called by muse, mutect2, varscan2
- HAUS5 | c.1725G>A p.E575= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV52548023; called by muse, mutect2, varscan2
- HAUS5 | c.1901G>A p.*634= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV99177746; called by muse, mutect2, varscan2
- HERC1 | c.12876C>T p.I4292= | Silent (SNP) | VAF 46/188 reads (24%) | catalogued as COSV71247903; called by muse, mutect2, varscan2
- HMCES | c.834C>G p.L278= | Silent (SNP) | VAF 19/185 reads (10%) | catalogued as COSV67300459; called by muse, mutect2, varscan2
- HMCN1 | c.1209C>G p.L403= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV54902112, COSV54922639; called by muse, mutect2, varscan2
- HORMAD2 | c.105G>A p.V35= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as rs1011884892, COSV60898796; called by muse, mutect2, varscan2
- HS3ST5 | c.972G>A p.L324= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as rs1262262860, COSV57140931; called by muse, mutect2, varscan2
- HSPA12B | c.564G>A p.L188= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV54765940, COSV54767119; called by muse, mutect2, varscan2
- IL10RA | c.615G>A p.V205= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV57140690; called by muse, mutect2, varscan2
- IL12B | c.840G>A p.K280= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV51455037; called by muse, mutect2, varscan2
- KAT2A | c.1078C>T p.L360= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV56790996; called by muse, mutect2, varscan2
- KCNH6 | c.1716C>T p.F572= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1161765043, COSV100120734; called by muse, mutect2
- KCNK15 | c.600C>T p.I200= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV65719577; called by muse, mutect2
- KDM1A | c.621G>A p.Q207= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV63088187; called by muse, mutect2, varscan2
- KIF2B | c.312G>A p.S104= | Silent (SNP) | VAF 83/234 reads (35%) | catalogued as rs543663752, COSV52129067, COSV52133640; called by muse, mutect2, varscan2
- KIFC1 | c.489G>A p.E163= | Silent (SNP) | VAF 18/152 reads (12%) | catalogued as COSV65737580; called by muse, mutect2, varscan2
- LDHD | c.1473C>G p.L491= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55580925; called by muse, mutect2, varscan2
- LHCGR | c.1596G>A p.L532= | Silent (SNP) | VAF 11/168 reads (7%) | catalogued as COSV54297301; called by muse, mutect2
- LMNA | c.1866C>T p.V622= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV61543015; called by muse, mutect2, varscan2
- LRATD1 | c.606C>G p.L202= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99706941; called by muse, mutect2
- LTB4R2 | c.514C>T p.L172= (on ENST00000528054; = p.L141= on NM_019839.5) | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs757180078, COSV51865827; called by muse, mutect2, varscan2
- MAPK10 | c.591C>T p.I197= (on ENST00000359221 / NM_001351625.2; = p.I235= on NM_002753.5) | Silent (SNP) | VAF 257/314 reads (82%) | catalogued as COSV60382767; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3135G>C p.P1045= | Silent (SNP) | VAF 60/80 reads (75%) | catalogued as COSV51600659; called by muse, mutect2, varscan2
- MAT1A | c.261C>T p.I87= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV64745056; called by muse, mutect2, varscan2
- METTL7A | c.114C>T p.Y38= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as rs755065263, COSV59840768; called by muse, mutect2
- MIDEAS | c.1830C>T p.I610= | Silent (SNP) | VAF 45/94 reads (48%) | catalogued as COSV54095075; called by muse, mutect2, varscan2
- MLPH | c.651C>A p.V217= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV52820714; called by muse, mutect2, varscan2
- MMP14 | c.75C>G p.L25= | Silent (SNP) | VAF 10/121 reads (8%) | catalogued as COSV61287654, COSV61288354; called by muse, mutect2
- MPP3 | c.678G>A p.E226= | Silent (SNP) | VAF 15/200 reads (8%) | catalogued as COSV68198227; called by muse, mutect2
- MROH6 | c.72G>A p.L24= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99434165; called by muse, mutect2
- MSH3 | c.33C>G p.L11= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV54150487, COSV54152343; called by muse, mutect2, varscan2
- MTF1 | c.1107C>A p.I369= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV65989228; called by muse, mutect2, varscan2
- MUC16 | c.5541C>T p.L1847= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as rs1374637982, COSV67464085, COSV67468252; called by muse, mutect2, varscan2
- MYH9 | c.5625C>G p.L1875= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV53386539; called by muse, mutect2
- N6AMT1 | c.12G>A p.E4= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs145160879, COSV58134509; called by muse, mutect2
- NDFIP1 | c.579C>G p.L193= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as rs754983410, COSV54074813; called by muse, mutect2, varscan2
- NECTIN1 | c.54C>T p.L18= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs761698010, COSV50600001; called by muse, mutect2, varscan2
- NEFL | c.948C>T p.T316= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV55337111; called by muse, mutect2, varscan2
- NEURL4 | c.912C>T p.S304= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs997034020, COSV59759104; called by muse, mutect2, varscan2
- NPC1L1 | c.2979C>T p.C993= | Silent (SNP) | VAF 91/209 reads (44%) | catalogued as COSV56925486; called by muse, mutect2, varscan2
- NPSR1 | c.30C>T p.F10= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs267601494, COSV62197912, COSV62198954; called by muse, mutect2, varscan2
- NPTX1 | c.690C>T p.L230= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as COSV60775053; called by muse, mutect2, varscan2
- NRP2 | c.841C>T p.L281= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV55928958, COSV55935782; called by muse, mutect2, varscan2
- OPRL1 | c.942C>G p.L314= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV61091781; called by muse, mutect2, varscan2
- ORAI3 | c.294C>T p.F98= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV52687966; called by muse, mutect2, varscan2
- OTUD6B | c.270G>C p.V90= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99575750; called by muse, mutect2, varscan2
- PACS2 | c.2085C>T p.D695= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs139536717, COSV57652912; called by muse, mutect2
- PAK5 | c.246C>T p.I82= | Silent (SNP) | VAF 59/184 reads (32%) | catalogued as COSV62023767; called by muse, mutect2, varscan2
- PARP15 | c.1707C>G p.V569= (on ENST00000464300 / NM_001113523.3; = p.V335= on NM_152615.2) | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV59972878; called by muse, mutect2
- PAX9 | c.379C>T p.L127= | Silent (SNP) | VAF 67/194 reads (35%) | catalogued as COSV64061635; called by muse, mutect2, varscan2
- PHACTR1 | c.477G>A p.L159= | Silent (SNP) | VAF 14/262 reads (5%) | catalogued as COSV60667638; called by muse, mutect2
- PIK3CA | c.801G>A p.L267= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV55994397, COSV99836471; called by muse, mutect2
- PKHD1 | c.4338C>T p.S1446= | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV61876741; called by muse, mutect2, varscan2
- PLA2G5 | c.96G>A p.V32= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV100908182; called by muse, mutect2
- POLR3B | c.3312C>T p.L1104= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as COSV57279368; called by muse, mutect2
- POP7 | c.159G>A p.Q53= | Silent (SNP) | VAF 30/259 reads (12%) | catalogued as COSV57450155; called by muse, mutect2, varscan2
- PPARG | c.1347G>A p.L449= (on ENST00000287820 / NM_015869.5; = p.L419= on NM_005037.7) | Silent (SNP) | VAF 81/136 reads (60%) | catalogued as COSV55142604; called by muse, mutect2, varscan2
- PPHLN1 | c.1323C>T p.L441= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV56731504; called by muse, mutect2, varscan2
- PPP2R5D | c.705C>T p.I235= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV55150655; called by muse, mutect2, varscan2
- PRPF6 | c.2825G>A p.*942= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV99411126; called by muse, mutect2, varscan2
- PRPSAP2 | c.504C>T p.F168= | Silent (SNP) | VAF 64/208 reads (31%) | catalogued as COSV52065840; called by muse, mutect2, varscan2
- PSG7 | c.1259G>A p.*420= | Silent (SNP) | VAF 49/88 reads (56%) | catalogued as rs765111858, COSV68444828; called by muse, mutect2, varscan2
- RAD54B | c.1710C>T p.F570= | Silent (SNP) | VAF 24/213 reads (11%) | catalogued as COSV60251728; called by muse, mutect2, varscan2
- RADIL | c.3225C>G p.L1075= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV68200935; called by muse, mutect2, varscan2
- RFK | c.246C>T p.I82= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs749657889, COSV65060917; called by muse, mutect2, varscan2
- RLF | c.1068C>T p.L356= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV65651928; called by muse, mutect2, varscan2
- RNASE13 | c.222G>A p.V74= | Silent (SNP) | VAF 7/164 reads (4%) | catalogued as COSV58794788; called by muse, mutect2
- RNASE3 | c.324C>T p.L108= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as COSV58959541; called by muse, mutect2, varscan2
- RNF20 | c.273G>A p.L91= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV66355679; called by muse, mutect2
- RNF213 | c.7681C>T p.L2561= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as rs1026639079, COSV100299459; called by muse, mutect2
- SERPINE2 | c.43C>T p.L15= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs771174822, COSV51457617; called by muse, mutect2
- SLC26A6 | c.1728G>A p.K576= | Silent (SNP) | VAF 73/160 reads (46%) | catalogued as COSV56572176; called by muse, mutect2, varscan2
- SLC2A8 | c.984C>T p.V328= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV64894569; called by muse, mutect2, varscan2
- SLC5A9 | c.528C>G p.L176= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV52583684; called by muse, mutect2
- SLC7A7 | c.303G>T p.G101= | Silent (SNP) | VAF 20/368 reads (5%) | catalogued as rs1291804749, COSV53540870; called by muse, mutect2
- SMCHD1 | c.5106G>A p.L1702= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV55257839; called by muse, mutect2
- SNTA1 | c.1029C>G p.L343= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54129292; called by muse, mutect2, varscan2
- SOWAHB | c.2145C>T p.T715= | Silent (SNP) | VAF 48/854 reads (6%) | catalogued as COSV57554549; called by muse, mutect2
- SPATA20 | c.1278C>T p.G426= (on ENST00000356488 / NM_001258372.1; = p.G442= on NM_022827.4) | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as COSV50066728; called by muse, mutect2
- SPHKAP | c.3480G>C p.L1160= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100763616, COSV100764545; called by muse, mutect2
- SPTB | c.750C>T p.L250= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs1476345998, COSV67632012; called by muse, mutect2, varscan2
- STAT4 | c.2196G>A p.L732= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as COSV61829992; called by muse, mutect2, varscan2
- STIM1 | c.288C>G p.L96= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV56154953; called by muse, mutect2, varscan2
- SULF1 | c.492G>A p.K164= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV52681669, COSV52694155; called by muse, varscan2
- SVIL | c.2892G>A p.E964= (on ENST00000355867 / NM_021738.3; = p.E538= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/236 reads (6%) | catalogued as COSV63443623; called by muse, mutect2
- SYNJ2BP | c.390C>T p.L130= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV56445739; called by muse, mutect2
- SZT2 | c.2436C>G p.L812= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as COSV65170075; called by muse, mutect2, varscan2
- TFAP2B | c.438G>A p.R146= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- TLR9 | c.603C>T p.L201= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV59726480; called by muse, mutect2
- TM9SF1 | c.1503C>T p.L501= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as COSV55779622; called by muse, mutect2, varscan2
- TMEM67 | c.1623G>A p.L541= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as COSV60039703; called by muse, mutect2, varscan2
- TMEM87A | c.117G>T p.R39= | Silent (SNP) | VAF 36/42 reads (86%) | catalogued as COSV56197981; called by muse, mutect2, varscan2
- TNXB | c.453G>C p.L151= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV64479536; called by muse, mutect2
- TOR3A | c.808C>T p.L270= | Silent (SNP) | VAF 57/117 reads (49%) | catalogued as COSV61680204; called by muse, mutect2, varscan2
- TTN | c.65397C>T p.L21799= (on ENST00000591111; = p.L14375= on NM_003319.4) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV60080852; called by muse, mutect2, varscan2
- USP39 | c.1224C>T p.L408= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV60381736; called by muse, mutect2, varscan2
- USP6 | c.618C>T p.F206= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV51483127, COSV51489290; called by muse, mutect2
- UTRN | c.5199G>A p.L1733= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV62336063; called by muse, mutect2, varscan2
- VPS13B | c.1203C>T p.F401= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV62019906; called by muse, mutect2, varscan2
- VPS54 | c.1845C>G p.V615= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV55440978; called by muse, mutect2, varscan2
- VWA1 | c.105G>A p.L35= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV58599937, COSV58600366; called by muse, mutect2
- WDR64 | c.2004T>C p.N668= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV63796183; called by muse, mutect2, varscan2
- WDR73 | c.222C>T p.F74= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as COSV101272967, COSV68321235; called by muse, mutect2, varscan2
- WNT9B | c.192G>A p.Q64= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV51518511; called by muse, mutect2
- WWC2 | c.1659C>T p.S553= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV66713893; called by muse, mutect2, varscan2
- XAB2 | c.1959G>A p.Q653= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV50335339; called by muse, mutect2, varscan2
- XAB2 | c.684C>T p.I228= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV64321744; called by muse, mutect2, varscan2
- XKR4 | c.441C>T p.L147= | Silent (SNP) | VAF 44/94 reads (47%) | catalogued as rs753158816, COSV59316543; called by muse, mutect2, varscan2
- XKRX | c.843C>T p.L281= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs772989506, COSV60708031; called by muse, mutect2, varscan2
- ZBP1 | c.420G>A p.V140= | Silent (SNP) | VAF 8/140 reads (6%) | catalogued as COSV59061915; called by muse, mutect2
- ZC3H11A | c.1449G>A p.L483= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV59746625; called by muse, mutect2, varscan2
- ZFAND2A | c.273G>A p.K91= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV57180368; called by muse, mutect2, varscan2
- ZFYVE19 | c.216G>A p.L72= | Silent (SNP) | VAF 25/33 reads (76%) | catalogued as COSV54540202; called by muse, mutect2, varscan2
- ZNF536 | c.2682C>T p.S894= | Silent (SNP) | VAF 17/217 reads (8%) | catalogued as rs761507089, COSV62824743; called by muse, mutect2
- ZSCAN1 | c.1005C>T p.L335= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs142150648; called by muse, mutect2
- AC074085.2 | n.278C>G | RNA (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- CARD14 | c.1851+157C>G | Intron (SNP) | VAF 19/166 reads (11%) | catalogued as COSV100712468, COSV60124804; called by muse, mutect2, varscan2
- DENND10P1 | n.1113G>C | RNA (SNP) | VAF 24/97 reads (25%) | called by muse, mutect2, varscan2
- EIF4A1 | c.205+163C>T | Intron (SNP) | VAF 19/271 reads (7%) | catalogued as COSV99548653; called by muse, mutect2
- FAM161A | c.1583+835C>G | Intron (SNP) | VAF 12/132 reads (9%) | catalogued as COSV100281072; called by muse, mutect2
- FOLH1B | n.1275G>C | RNA (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- MIR543 | n.9G>A | RNA (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- PDE4B | c.634+626G>C | Intron (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100301906; called by muse, mutect2
- SNORD115-32 | n.61C>T | RNA (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- TM9SF1 | c.1427+39C>T | Intron (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55779058, COSV55779630, COSV99938056; called by muse, mutect2, varscan2
